Somatic mutation profile of tumor specimen MP2PRT-PASNNZ-TBP1-A (aliquot MP2PRT-PASNNZ-TBP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASNNZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,636 days).
Specimen MP2PRT-PASNNZ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b0ab0f5-779c-48a2-9934-227ef54f5eda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNNZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNNZ-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea6eacdd-dae9-4004-8059-cbcbd32243c6

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- POM121L12 | c.311G>C p.G104A | Missense Mutation (SNP) | VAF 72/599 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.075); catalogued as COSV101374960, COSV68693781; called by muse, mutect2, varscan2
- MYH9 | c.1881G>T p.M627I | Missense Mutation (SNP) | VAF 29/548 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- RB1CC1 | c.3370G>T p.E1124* | Nonsense Mutation (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
- USP43 | c.2831C>A p.P944Q | Missense Mutation (SNP) | VAF 17/431 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.047); called by muse, mutect2
- KDM6A | c.1953G>A p.S651= | Silent (SNP) | VAF 140/274 reads (51%) | catalogued as rs541289730, COSV100938021; called by muse, mutect2, varscan2
- ZNF165 | c.531C>T p.P177= | Silent (SNP) | VAF 26/380 reads (7%) | called by muse, mutect2
